Somatic mutation profile of tumor specimen C3L-03961-02 (aliquot CPT0232640006) from CPTAC case C3L-03961, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 48.6 years (17,760 days).
Specimen C3L-03961-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fb5127f-cf65-47ce-a136-5eddd6d105c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03961-31 (Blood Derived Normal), aliquot CPT0232790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f8f2a5d-41f7-4392-8746-20eed047f616

The open-access MAF lists 283 somatic variants for this specimen: 191 protein-altering or splice-affecting, 62 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 62, Nonsense Mutation 18, Intron 15, Splice Site 5, RNA 5, 5'Flank 4, 5'UTR 3, 3'UTR 3, Frame Shift Del 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HBB | c.320T>A p.L107Q | Missense Mutation (SNP) | VAF 70/601 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs33941844, CM066098, CM910591, CM930377; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.15088C>T p.R5030C | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555185875, CM138453, COSV56417619; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 96/590 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780075, CM921040, COSV52675189, COSV52691512, COSV52734317, COSV52740807; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA3 | c.2393T>A p.L798H | Missense Mutation (SNP) | VAF 111/836 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM140155; called by muse, mutect2, varscan2
- ADGRF5 | c.3224A>G p.Q1075R | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs777064110; called by muse, mutect2
- ARHGAP31 | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51795926, COSV51798037; called by muse, mutect2
- BRINP2 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 59/276 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100838529, COSV64175535; called by muse, mutect2, varscan2
- BRINP3 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 89/342 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100819096, COSV66522458; called by muse, mutect2, varscan2
- BTK | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as CM092943; called by muse, mutect2, varscan2
- BUD13 | c.1228C>G p.R410G | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52767001; called by muse, mutect2, varscan2
- CC2D1B | c.1241A>G p.H414R | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756485707; called by muse, mutect2, varscan2
- CCDC198 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs765934485; called by muse, mutect2
- CCKBR | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 47/308 reads (15%) | catalogued as COSV58100346; called by muse, mutect2, varscan2
- CD74 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1195416511, COSV50533404; called by muse, mutect2, varscan2
- CDH20 | c.1020C>G p.P340= | Splice Region (SNP) | VAF 18/170 reads (11%) | catalogued as COSV53007423; called by muse, varscan2
- CDKN2A | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 114/690 reads (17%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.868); catalogued as COSV100445869; called by muse, mutect2, varscan2
- CMYA5 | c.6092C>A p.P2031H | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs1297988995; called by muse, mutect2, varscan2
- COL1A2 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 59/626 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1562900943; ClinVar: uncertain significance; called by muse, mutect2
- COL6A5 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 31/114 reads (27%) | catalogued as COSV55195642; called by muse, mutect2, varscan2
- CTNNA2 | c.2408G>T p.G803V | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58166035, COSV58166338; called by muse, mutect2
- DDRGK1 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV63227593; called by muse, mutect2, varscan2
- DNAH5 | c.12432G>C p.Q4144H | Missense Mutation (SNP) | VAF 62/576 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54227119; called by muse, mutect2, varscan2
- DRAM2 | c.221G>C p.R74P | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54414825; called by muse, mutect2, varscan2
- DRG1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs148069806, COSV100513783; called by muse, mutect2, varscan2
- EYS | c.6669G>T p.L2223F | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV65550603; called by muse, mutect2
- FBN3 | c.5466G>A p.M1822I | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV99560948; called by muse, mutect2, varscan2
- GLIS3 | c.1332C>G p.C444W | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430943510; called by muse, mutect2, varscan2
- HGS | c.917G>T p.S306I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV61266678; called by muse, mutect2, varscan2
- IAPP | c.161A>C p.N54T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV53713241; called by muse, mutect2
- IGHV3-66 | c.231C>G p.Y77* | Nonsense Mutation (SNP) | VAF 50/526 reads (10%) | catalogued as rs1555572942; called by muse, mutect2
- IGLV2-18 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 84/672 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs372445871; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56249087; called by muse, varscan2
- ISY1-RAB43 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99860755; called by muse, mutect2
- JAK3 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 51/453 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs376945173; called by muse, mutect2, varscan2
- KCNK13 | c.525C>A p.S175R | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs1566654578; called by muse, mutect2, varscan2
- KLK3 | c.296C>G p.P99R | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58099470; called by muse, mutect2, varscan2
- KRTAP10-4 | c.935A>C p.Q312P | Missense Mutation (SNP) | VAF 185/906 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782419771; called by mutect2, varscan2
- KRTAP5-11 | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 64/648 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as rs760329612; called by muse, mutect2
- LYST | c.1421A>G p.N474S | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs531780017; called by muse, mutect2, varscan2
- MAPK4 | c.310G>T p.V104F | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV68541257; called by muse, mutect2, varscan2
- MLLT3 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 92/524 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV100580935; called by muse, varscan2
- MPHOSPH8 | c.1024A>G p.R342G | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs758591755; called by muse, mutect2, varscan2
- MUC16 | c.22727G>A p.R7576K | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs770645457; called by muse, mutect2, varscan2
- MUC6 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as rs1249510635; called by muse, mutect2, varscan2
- NELL1 | c.1220G>T p.C407F | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54273964, COSV54310418; called by muse, mutect2
- NF1 | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.784); catalogued as rs745611945, CD153879; called by muse, mutect2
- NLRP8 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.201); catalogued as rs765907009, COSV99404735; called by muse, mutect2, varscan2
- OAS3 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 38/365 reads (10%) | catalogued as COSV57445993; called by muse, mutect2, varscan2
- OR14C36 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs374342974; called by muse, mutect2, varscan2
- OR4A47 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 48/370 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.097); catalogued as rs750401492, COSV71445108; called by muse, mutect2
- OR4P4 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV58923701; called by muse, mutect2
- PCDHA5 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 59/559 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs782648661, COSV100972241; called by muse, mutect2, varscan2
- PCDHB16 | c.1034C>G p.P345R | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1006374044; called by muse, mutect2, varscan2
- PCK1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.668); catalogued as rs771938481; called by muse, mutect2, varscan2
- PCLO | c.13909C>T p.P4637S | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61676148; called by muse, mutect2
- PEX5L | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs1056608865; called by muse, mutect2, varscan2
- PIEZO2 | c.1463C>G p.A488G | Missense Mutation (SNP) | VAF 23/317 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.694); catalogued as COSV100124358; called by muse, mutect2
- PPM1E | c.830G>C p.G277A | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100375833; called by muse, mutect2, varscan2
- PTPRC | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV61406528; called by muse, mutect2, varscan2
- PUS1 | c.1115A>T p.H372L | Missense Mutation (SNP) | VAF 50/305 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100435148; called by muse, mutect2, varscan2
- RCC1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs772755509, COSV65780338; called by muse, mutect2, varscan2
- ROBO3 | c.3189G>T p.K1063N | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV67302271; called by muse, mutect2
- SCN7A | c.3098G>A p.R1033Q | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355692072, COSV69272739; called by muse, mutect2, varscan2
- SKIDA1 | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV71611160; called by muse, mutect2
- SLC22A18AS | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.125); catalogued as rs752201257; called by muse, mutect2
- SLITRK3 | c.2231C>A p.P744H | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99580502; called by muse, mutect2, varscan2
- SPANXN3 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 34/260 reads (13%) | catalogued as COSV65140682; called by muse, mutect2, varscan2
- SPTBN4 | c.3556G>C p.G1186R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.525); catalogued as COSV100150856; called by muse, mutect2
- ST8SIA3 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 26/341 reads (8%) | PolyPhen possibly damaging (0.76); catalogued as COSV100129611; called by muse, mutect2
- SYNE1 | c.12266A>T p.Y4089F (on ENST00000367255 / NM_182961.4; = p.Y4018F on NM_033071.3) | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1294787806; called by muse, mutect2, varscan2
- TBX18 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); catalogued as rs762141083; called by muse, mutect2, varscan2
- TESC | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 25/323 reads (8%) | catalogued as rs772915105, COSV58813731; called by muse, mutect2
- TG | c.7382T>C p.V2461A | Missense Mutation (SNP) | VAF 84/621 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs748678686; called by muse, mutect2, varscan2
- UBR2 | c.1858G>A p.G620S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100867352; called by muse, varscan2
- USP10 | c.440G>C p.R147T | Missense Mutation (SNP) | VAF 58/493 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs777036707; called by muse, mutect2, varscan2
- VPS13A | c.4517A>G p.Y1506C | Missense Mutation (SNP) | VAF 76/408 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749572299; called by muse, mutect2, varscan2
- ZFHX4 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs777665830, COSV51464830; called by muse, mutect2
- ZFHX4 | c.7085A>G p.K2362R | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.632); catalogued as rs767480864; called by muse, mutect2, varscan2
- ZIK1 | c.1432C>T p.L478F | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56736755; called by muse, mutect2, varscan2
- ABCC12 | c.1029A>T p.Q343H | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ABCC8 | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ADAM2 | c.483A>T p.R161S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADAM2 | c.267+1G>T p.X89_splice | Splice Site (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- ADGRA1 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 48/357 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AHNAK2 | c.15775G>A p.A5259T | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- AKAP6 | c.5420G>A p.R1807K | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ANO9 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AP5B1 | c.2459T>C p.V820A | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ATP8A2 | c.842G>A p.W281* | Nonsense Mutation (SNP) | VAF 19/193 reads (10%) | called by muse, mutect2, varscan2
- BCHE | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C2orf74 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2
- C6orf163 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC102B | c.1434+1G>C p.X478_splice | Splice Site (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- CDH20 | c.1547G>C p.S516T | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.458); called by muse, mutect2
- CEP162 | c.3080T>C p.L1027P | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEP250 | c.2993G>T p.S998I | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CLSPN | c.3857A>G p.H1286R | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CNTN3 | c.2677A>T p.T893S | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL13A1 | c.366A>T p.G122= | Splice Region (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- COL3A1 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2
- CXCL2 | c.158A>T p.H53L | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- DEGS1 | c.82+1del | Frame Shift Del (DEL) | VAF 22/116 reads (19%) | called by mutect2, pindel, varscan2
- DISP3 | c.2389del p.L797Cfs*40 | Frame Shift Del (DEL) | VAF 43/344 reads (13%) | called by mutect2, pindel, varscan2
- DSCAM | c.4648G>T p.V1550L | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DUOX1 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DUOX2 | c.2525G>T p.R842L | Missense Mutation (SNP) | VAF 93/802 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- EGFL6 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- FASTKD1 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- FER1L6 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- FER1L6 | c.3034G>T p.V1012L | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FJX1 | c.356A>T p.H119L | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXD4L4 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 96/1085 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GABRR1 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.021); called by muse, mutect2
- GATM | c.1075T>A p.S359T | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2
- GFPT2 | c.1842G>T p.Q614H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GOLGA8J | c.1192C>A p.L398I | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by mutect2, varscan2
- GPR42 | c.569T>A p.V190E | Missense Mutation (SNP) | VAF 86/456 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- GRIN3A | c.2110A>T p.T704S | Missense Mutation (SNP) | VAF 47/390 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRXCR1 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTF3C2 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- HCRT | c.115T>C p.C39R | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HEATR5B | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- IGSF21 | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.222); called by mutect2, varscan2
- IRS4 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 22/662 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- ISLR2 | c.1648G>T p.V550F | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIF6 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIT | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KLHL4 | c.403A>T p.I135L | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP5-11 | c.244T>C p.C82R | Missense Mutation (SNP) | VAF 62/652 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2
- LMNTD1 | c.638C>A p.A213E | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- LRFN2 | c.949A>T p.S317C | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- LRFN5 | c.1467A>G p.I489M | Missense Mutation (SNP) | VAF 31/348 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.254); called by muse, mutect2
- MAGEB5 | c.805A>T p.S269C | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2
- MAPK8IP3 | c.1581G>T p.E527D | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MDGA2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 35/234 reads (15%) | called by muse, mutect2, varscan2
- NID2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NKX2-2 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR3 | c.152A>C p.Q51P | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- NT5DC4 | c.1248+1G>C p.X416_splice | Splice Site (SNP) | VAF 31/259 reads (12%) | called by muse, mutect2, varscan2
- OCSTAMP | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2, varscan2
- OR10Q1 | c.810C>G p.S270R | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- OR14C36 | c.415T>A p.C139S | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOG | c.8683C>A p.Q2895K | Missense Mutation (SNP) | VAF 87/712 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- PCDH19 | c.2205G>T p.K735N | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- PEAK1 | c.2828A>G p.K943R | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHA3 | c.380T>A p.L127* | Nonsense Mutation (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- PLEKHG4B | c.1540G>T p.E514* (on ENST00000283426; = p.E870* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- PLXNC1 | c.2890G>T p.G964W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2
- POLK | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2
- POTEB3 | c.395G>T p.R132M | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); called by mutect2, varscan2
- POTEF | c.1117A>T p.S373C | Missense Mutation (SNP) | VAF 29/400 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, mutect2
- PPP1R3A | c.2976C>A p.C992* | Nonsense Mutation (SNP) | VAF 33/422 reads (8%) | called by muse, mutect2
- PPP4R3C | c.1882A>T p.N628Y | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- PRDM13 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM6 | c.1508G>A p.C503Y | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRDM9 | c.682A>T p.S228C | Missense Mutation (SNP) | VAF 64/602 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RAB3GAP2 | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RGL1 | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); called by muse, mutect2
- SETBP1 | c.4541A>T p.H1514L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- SLC6A15 | c.1573G>T p.D525Y | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SNTA1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- SPHKAP | c.3954G>A p.M1318I | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ST8SIA3 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 32/277 reads (12%) | PolyPhen benign (0.113); called by muse, mutect2, varscan2
- STK39 | c.1002C>A p.C334* | Nonsense Mutation (SNP) | VAF 29/316 reads (9%) | called by muse, mutect2
- SYT10 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYT4 | c.452A>T p.Q151L | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.15); called by muse, mutect2
- TDRD15 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TERT | c.2818C>A p.L940M | Missense Mutation (SNP) | VAF 46/397 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TEX15 | c.4513A>T p.K1505* (on ENST00000256246; = p.K1888* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- TMC8 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- TMEM132C | c.206A>T p.Q69L | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- TMOD1 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TNIP1 | c.1780-2A>T p.X594_splice | Splice Site (SNP) | VAF 26/338 reads (8%) | called by muse, mutect2
- TRGC1 | c.345G>C p.M115I | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- TRIM51GP | c.1041G>T p.M347I | Missense Mutation (SNP) | VAF 62/580 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM6 | c.831G>C p.M277I | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPS1 | c.1007A>T p.K336I (on ENST00000220888 / NM_001330599.2; = p.K349I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.4979T>A p.L1660* (on ENST00000591111; = p.L1614* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 34/135 reads (25%) | called by muse, mutect2, varscan2
- UBR1 | c.3509+2T>G p.X1170_splice | Splice Site (SNP) | VAF 73/523 reads (14%) | called by muse, mutect2, varscan2
- XPO1 | c.2089A>T p.R697* | Nonsense Mutation (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2
- ZC3H13 | c.1976G>T p.R659I | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZCCHC14 | c.884C>T p.T295I (on ENST00000268616; = p.T432I on NM_015144.3) | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZDHHC17 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFPM1 | c.2624T>A p.L875Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF180 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- ZNF292 | c.5359G>C p.A1787P | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- ZNF420 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.321); called by muse, mutect2
- ZNF492 | c.602A>C p.E201A | Missense Mutation (SNP) | VAF 30/317 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- ZNF695 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2
- ZNF804B | c.3890G>C p.G1297A | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF846 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2
- AKAP13 | c.2073A>G p.E691= | Silent (SNP) | VAF 29/219 reads (13%) | called by muse, mutect2, varscan2
- AMN1 | c.60G>A p.K20= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV55673048; called by muse, mutect2, varscan2
- AMPH | c.474C>T p.S158= | Silent (SNP) | VAF 26/231 reads (11%) | called by muse, mutect2, varscan2
- ANKRD26 | c.327T>C p.C109= | Silent (SNP) | VAF 154/602 reads (26%) | catalogued as rs1183431335; called by muse, mutect2, varscan2
- APOB | c.5445G>A p.R1815= | Silent (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF37 | c.385T>C p.L129= | Silent (SNP) | VAF 45/415 reads (11%) | called by muse, mutect2, varscan2
- ASAH1 | c.1053G>A p.T351= | Silent (SNP) | VAF 42/478 reads (9%) | catalogued as rs779213576; called by muse, mutect2
- BBX | c.1467C>T p.T489= | Silent (SNP) | VAF 21/307 reads (7%) | catalogued as COSV100362117; called by muse, mutect2
- CBY2 | c.639G>T p.R213= | Silent (SNP) | VAF 30/188 reads (16%) | catalogued as COSV60117756; called by muse, mutect2, varscan2
- CCDC141 | c.2928A>G p.P976= | Silent (SNP) | VAF 28/290 reads (10%) | catalogued as rs1236330130; called by muse, mutect2
- CCKBR | c.618G>T p.V206= | Silent (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2
- CENPH | c.319A>C p.R107= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- CIC | c.2223C>A p.A741= | Silent (SNP) | VAF 83/635 reads (13%) | called by muse, mutect2, varscan2
- CSMD1 | c.1581G>T p.G527= (on ENST00000520002; = p.G526= on NM_033225.6) | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- DCAF8L1 | c.1494C>T p.T498= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV101491520; called by muse, mutect2, varscan2
- DHX37 | c.1224G>T p.S408= | Silent (SNP) | VAF 43/388 reads (11%) | catalogued as COSV58136151; called by muse, mutect2, varscan2
- DNAH17 | c.3918T>C p.V1306= | Silent (SNP) | VAF 39/333 reads (12%) | called by muse, mutect2, varscan2
- DNAH5 | c.5220C>G p.A1740= | Silent (SNP) | VAF 34/397 reads (9%) | called by muse, mutect2
- ELL | c.1248G>T p.A416= | Silent (SNP) | VAF 28/199 reads (14%) | catalogued as COSV53211863; called by muse, mutect2, varscan2
- FCHO1 | c.2535C>A p.P845= | Silent (SNP) | VAF 28/286 reads (10%) | called by muse, mutect2, varscan2
- GABRG2 | c.1458G>T p.R486= (on ENST00000361925 / NM_001375343.1; = p.R446= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/333 reads (11%) | catalogued as COSV100729593, COSV100729651; called by muse, mutect2, varscan2
- GALNT17 | c.1461C>T p.H487= | Silent (SNP) | VAF 26/180 reads (14%) | called by muse, mutect2, varscan2
- GATAD2B | c.243G>A p.G81= | Silent (SNP) | VAF 88/413 reads (21%) | called by muse, mutect2, varscan2
- GGA2 | c.1029C>T p.C343= | Silent (SNP) | VAF 26/222 reads (12%) | catalogued as rs1439155557; called by muse, mutect2, varscan2
- GLB1L3 | c.1110A>T p.A370= | Silent (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2, varscan2
- GLIS3 | c.63C>T p.N21= | Silent (SNP) | VAF 98/622 reads (16%) | catalogued as COSV60930571; called by muse, mutect2, varscan2
- GOLGA6L2 | c.2046G>A p.V682= | Silent (SNP) | VAF 57/827 reads (7%) | catalogued as rs769917879; called by muse, mutect2
- GPR150 | c.21C>A p.P7= | Silent (SNP) | VAF 28/286 reads (10%) | catalogued as COSV66168439; called by muse, mutect2
- GUCY2F | c.1593C>T p.S531= | Silent (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- H1-8 | c.609G>A p.A203= | Silent (SNP) | VAF 56/590 reads (9%) | catalogued as rs192410545, COSV60974646; called by muse, mutect2
- HAS1 | c.18G>T p.A6= | Silent (SNP) | VAF 26/188 reads (14%) | catalogued as COSV55788471; called by muse, mutect2
- HMCN2 | c.2335C>T p.L779= | Silent (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- IDH3B | c.483G>T p.V161= | Silent (SNP) | VAF 84/621 reads (14%) | catalogued as rs748899512; called by muse, mutect2, varscan2
- ITGA1 | c.2646T>C p.H882= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- KCNK18 | c.81C>G p.L27= | Silent (SNP) | VAF 76/648 reads (12%) | called by muse, mutect2, varscan2
- LAIR1 | c.795G>T p.R265= | Silent (SNP) | VAF 24/249 reads (10%) | catalogued as rs1286209288; called by muse, mutect2
- LRP1B | c.7962G>T p.L2654= | Silent (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- LRRC73 | c.909G>A p.T303= | Silent (SNP) | VAF 40/323 reads (12%) | catalogued as rs369136757; called by muse, mutect2, varscan2
- MYT1L | c.3348C>A p.L1116= | Silent (SNP) | VAF 25/237 reads (11%) | catalogued as COSV67701521; called by muse, mutect2, varscan2
- NID1 | c.339G>T p.T113= | Silent (SNP) | VAF 80/293 reads (27%) | catalogued as COSV51626519; called by muse, mutect2, varscan2
- OR10S1 | c.748C>A p.R250= | Silent (SNP) | VAF 25/233 reads (11%) | catalogued as COSV73342827; called by muse, mutect2, varscan2
- OR2M3 | c.210C>T p.D70= | Silent (SNP) | VAF 43/251 reads (17%) | catalogued as rs768597426; called by muse, mutect2, varscan2
- PCDHA1 | c.1896C>T p.S632= | Silent (SNP) | VAF 52/482 reads (11%) | called by muse, mutect2, varscan2
- PCDHB7 | c.618A>G p.P206= | Silent (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- PKHD1 | c.1245C>G p.A415= | Silent (SNP) | VAF 25/304 reads (8%) | called by muse, mutect2
- PLXNB2 | c.1005G>T p.R335= | Silent (SNP) | VAF 40/361 reads (11%) | called by muse, mutect2, varscan2
- PSD2 | c.667C>A p.R223= | Silent (SNP) | VAF 35/265 reads (13%) | catalogued as rs374016750; called by muse, mutect2, varscan2
- PTPN21 | c.1533G>T p.P511= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs145218668; called by muse, mutect2, varscan2
- RCSD1 | c.69G>C p.L23= | Silent (SNP) | VAF 31/310 reads (10%) | called by muse, mutect2
- SCUBE2 | c.12G>T p.A4= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- SDF2L1 | c.225G>A p.S75= | Silent (SNP) | VAF 67/506 reads (13%) | catalogued as rs933313566; called by muse, mutect2, varscan2
- SF3A3 | c.774G>T p.L258= | Silent (SNP) | VAF 46/258 reads (18%) | called by muse, mutect2, varscan2
- SHISA6 | c.549G>T p.G183= | Silent (SNP) | VAF 89/716 reads (12%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.1212C>A p.T404= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- SMOX | c.1605C>T p.S535= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as rs765404156; called by muse, mutect2, varscan2
- SVEP1 | c.7536G>T p.T2512= | Silent (SNP) | VAF 19/340 reads (6%) | called by muse, mutect2
- TBXT | c.1218G>A p.A406= | Silent (SNP) | VAF 50/421 reads (12%) | catalogued as rs1157647187, COSV51619756; called by muse, mutect2, varscan2
- TMEM132C | c.1027C>A p.R343= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV100176717; called by muse, mutect2, varscan2
- VPS39 | c.381A>G p.T127= (on ENST00000348544 / NM_001301138.2; = p.T116= on NM_015289.5) | Silent (SNP) | VAF 21/263 reads (8%) | called by muse, mutect2
- ZFYVE16 | c.3915C>T p.A1305= | Silent (SNP) | VAF 22/205 reads (11%) | catalogued as rs1242340466; called by muse, mutect2, varscan2
- ZHX1 | c.1080G>T p.V360= | Silent (SNP) | VAF 16/183 reads (9%) | called by muse, mutect2
- ZNF469 | c.10543C>T p.L3515= (on ENST00000437464; = p.L3543= on NM_001367624.2) | Silent (SNP) | VAF 27/241 reads (11%) | called by muse, mutect2, varscan2
- ADH5P5 | chr5:23977796 G>T | 5'Flank (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83317T>G | Intron (SNP) | VAF 62/852 reads (7%) | called by muse, mutect2
- AP001007.2 | n.420G>T | RNA (SNP) | VAF 43/355 reads (12%) | called by muse, varscan2
- APTX | c.875-28G>T | Intron (SNP) | VAF 65/527 reads (12%) | called by muse, mutect2, varscan2
- BCAR1 | chr16:75266767 G>T | 5'Flank (SNP) | VAF 6/35 reads (17%) | catalogued as rs760434044; called by muse, mutect2, varscan2
- C11orf40 | n.223C>A | RNA (SNP) | VAF 24/274 reads (9%) | called by muse, mutect2
- CARD9 | c.1078-114C>A | Intron (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- CCDC162P | n.4125G>C | RNA (SNP) | VAF 34/229 reads (15%) | catalogued as rs946565074; called by muse, mutect2, varscan2
- CDH9 | c.999+82G>T | Intron (SNP) | VAF 24/299 reads (8%) | called by muse, mutect2
- CSF1R | c.-23C>A | 5'UTR (SNP) | VAF 32/188 reads (17%) | called by muse, mutect2, varscan2
- ERGIC3 | c.367+739G>A | Intron (SNP) | VAF 12/187 reads (6%) | catalogued as rs889814327; called by muse, mutect2
- HLA-DQB2 | c.*780G>T | 3'UTR (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- KLRC3 | c.678+15T>C | Intron (SNP) | VAF 13/179 reads (7%) | catalogued as rs1269668147; called by muse, mutect2
- MOGAT3 | chr7:101202531 G>A | 5'Flank (SNP) | VAF 40/357 reads (11%) | called by muse, mutect2
- MS4A8 | c.534+9C>A | Intron (SNP) | VAF 22/223 reads (10%) | called by muse, mutect2, varscan2
- MXD3 | c.177-21C>T | Intron (SNP) | VAF 29/262 reads (11%) | catalogued as rs759881449; called by muse, mutect2, varscan2
- NOC2LP2 | n.1055C>A | RNA (SNP) | VAF 33/412 reads (8%) | called by muse, mutect2
- NOG | c.*30C>A | 3'UTR (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- NRN1L | chr16:67884836 C>T | 5'Flank (SNP) | VAF 68/510 reads (13%) | called by muse, varscan2
- PDE10A | c.106+91812G>T | Intron (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2
- PLEKHA1 | c.681+12del | Intron (DEL) | VAF 26/120 reads (22%) | catalogued as COSV64569565; called by mutect2, pindel, varscan2
- PLEKHG2 | c.*6G>T | 3'UTR (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2
- RGPD4 | c.-48G>C | 5'UTR (SNP) | VAF 46/474 reads (10%) | called by muse, mutect2
- SNX6 | c.42+22G>C | Intron (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- SSPOP | n.7532C>A | RNA (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- TAZ | c.-23C>G | 5'UTR (SNP) | VAF 17/429 reads (4%) | called by muse, mutect2
- TLR8 | c.3+3670del | Intron (DEL) | VAF 14/135 reads (10%) | called by mutect2, pindel, varscan2
- UQCRB | c.259-256C>T | Intron (SNP) | VAF 17/206 reads (8%) | called by muse, mutect2
- XKR4 | c.806+60844C>G | Intron (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1163C>A | Intron (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
